Somatic mutation profile of tumor specimen TCGA-QK-AA3K-01A (aliquot TCGA-QK-AA3K-01A-11D-A391-08) from TCGA case TCGA-QK-AA3K, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 60.5 years (22,093 days).
Specimen TCGA-QK-AA3K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ece4ba4e-ef2e-4db9-a97f-c91039e50ab1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QK-AA3K-10A (Blood Derived Normal), aliquot TCGA-QK-AA3K-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3efaeb18-d5aa-41ff-a9db-49c7c12cdfad

The open-access MAF lists 107 somatic variants for this specimen: 78 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 27, Frame Shift Del 6, Nonsense Mutation 4, Intron 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NOTCH1 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 102/181 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1057523819, COSV53030190; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 10/41 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 35/83 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC006059.2 | c.726G>C p.L242F | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.328); catalogued as COSV100045055; called by muse, mutect2, varscan2
- ACO1 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs376485136; called by muse, mutect2, varscan2
- AHNAK2 | c.8560G>T p.G2854W | Missense Mutation (SNP) | VAF 38/343 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100314886, COSV100319241, COSV60908726; called by muse, mutect2, varscan2
- AKAP5 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV100277818; called by muse, mutect2, varscan2
- AKAP5 | c.128C>A p.A43E | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV100277822; called by muse, mutect2, varscan2
- AKAP9 | c.8935A>T p.M2979L (on ENST00000359028; = p.M2955L on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV100661836; called by muse, mutect2, varscan2
- ASTN1 | c.3480C>G p.I1160M | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100705339; called by muse, mutect2
- BBOX1 | c.37G>T p.G13W | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV99074182; called by muse, mutect2, varscan2
- BRS3 | c.367C>T p.L123F | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV101036392; called by muse, mutect2, varscan2
- C10orf88 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.278); catalogued as COSV100924992; called by muse, mutect2, varscan2
- CAPN9 | c.2032C>G p.L678V | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV99679827; called by muse, mutect2, varscan2
- CIITA | c.2899G>C p.V967L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs201571405, COSV100161276; called by muse, mutect2, varscan2
- CNOT1 | c.1612A>G p.I538V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs770425261, COSV100408348; called by muse, mutect2, varscan2
- CRADD | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs534423825, COSV60554940; called by muse, mutect2, varscan2
- DMRTA1 | c.632A>C p.E211A | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as COSV100364606; called by muse, mutect2, varscan2
- DNAH5 | c.13685A>G p.E4562G | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as COSV99444035; called by muse, mutect2, varscan2
- DNAH9 | c.2735G>A p.C912Y | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV99303437; called by muse, mutect2, varscan2
- DVL1 | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs1356138225, COSV100229189; called by muse, mutect2, varscan2
- EGR1 | c.157G>C p.G53R | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as COSV99525224; called by muse, mutect2, varscan2
- EIF4A3 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs757676343, COSV53922033; called by muse, mutect2, varscan2
- EXOC5 | c.1405G>T p.G469* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100566923; called by muse, mutect2, varscan2
- FARP1 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV60340118; called by muse, mutect2, varscan2
- FRMD8 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs201911015, COSV100454551; called by muse, mutect2, varscan2
- GABBR1 | c.1170G>A p.W390* | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | catalogued as COSV100589379; called by muse, mutect2, varscan2
- HERC3 | c.464-1G>C p.X155_splice | Splice Site (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99985202; called by muse, mutect2
- ITGA4 | c.2299G>C p.A767P | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.379); catalogued as rs369569983; called by mutect2, varscan2
- KCNF1 | c.1070T>A p.I357N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99705484; called by muse, mutect2, varscan2
- LMLN | c.1533T>A p.F511L | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100218261; called by muse, mutect2, varscan2
- MARCHF1 | c.487G>A p.V163I (on ENST00000274056; = p.V146I on NM_017923.4) | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs752184817, COSV99919754; called by muse, mutect2
- METTL5 | c.526A>G p.I176V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs368389812; called by mutect2, varscan2
- MTMR10 | c.2271A>T p.L757F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100075792; called by muse, mutect2
- NSUN6 | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs749356061, COSV101045290; called by muse, mutect2, varscan2
- NUP133 | c.3058C>A p.L1020I | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.673); catalogued as COSV99772488; called by muse, mutect2, varscan2
- NUP214 | c.1560C>A p.F520L | Missense Mutation (SNP) | VAF 78/142 reads (55%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.945); catalogued as COSV100845080, COSV63907227; called by muse, mutect2, varscan2
- OR6B3 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100096812; called by muse, mutect2, varscan2
- OR6N2 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as rs141853976, COSV59409940; called by muse, mutect2, varscan2
- PCDH11X | c.1686T>G p.D562E | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100007447; called by muse, mutect2, varscan2
- PCDHA13 | c.958G>A p.V320M | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV56552969; called by muse, mutect2, varscan2
- PEAK1 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.174); catalogued as rs1460934683, COSV56937783; called by muse, mutect2, varscan2
- PPHLN1 | c.155A>T p.Y52F | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV99871388; called by muse, mutect2, varscan2
- PTPRH | c.2221G>A p.V741M | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs147064563, COSV99670606; called by muse, mutect2, varscan2
- PTPRH | c.919G>T p.A307S | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.053); catalogued as COSV54744287, COSV99670607; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773249438, COSV52964786; called by muse, mutect2
- RAPGEF1 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as COSV64701224; called by muse, mutect2, varscan2
- RBMS2 | c.946C>A p.P316T | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as rs1001477956, COSV100008310; called by muse, mutect2, varscan2
- RNF216 | c.938A>G p.Y313C (on ENST00000425013 / NM_207116.3; = p.Y370C on NM_207111.4) | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV101111251; called by muse, mutect2, varscan2
- RREB1 | c.1804A>G p.I602V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.067); catalogued as COSV100619065; called by muse, mutect2, varscan2
- RYR3 | c.10300G>A p.V3434I (on ENST00000389232; = p.V3435I on NM_001036.6) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV101211852; called by muse, varscan2
- SBK1 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs748701315, COSV100543368; called by muse, mutect2, varscan2
- SH2B3 | c.1006G>C p.D336H | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV100373959; called by muse, mutect2, varscan2
- SLC22A6 | c.1197G>A p.M399I | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV100842778; called by muse, mutect2
- SLFN11 | c.365A>T p.K122M | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.299); catalogued as COSV100390287; called by muse, mutect2
- SORT1 | c.1077C>A p.D359E | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV99860418; called by muse, mutect2, varscan2
- STK31 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as COSV100669060, COSV63454164; called by muse, mutect2, varscan2
- THAP5 | c.943A>G p.T315A (on ENST00000415914 / NM_001130475.3; = p.T273A on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1373812635, COSV100542756; called by muse, mutect2, varscan2
- TKFC | c.1615G>A p.A539T | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53651641; called by muse, mutect2, varscan2
- TKTL2 | c.300C>A p.N100K | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as COSV99761033; called by muse, mutect2, varscan2
- TNXB | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs907925140, COSV100925703; called by muse, mutect2, varscan2
- UBE2M | c.145A>G p.I49V | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV53043033, COSV99284991; called by muse, varscan2
- UBE3B | c.584A>G p.N195S | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.767); catalogued as rs1364356672, COSV99783575; called by muse, mutect2, varscan2
- UNC13C | c.1841A>T p.Q614L | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV99510574; called by muse, mutect2, varscan2
- WWP2 | c.2133G>A p.W711* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as COSV63128386; called by muse, mutect2, varscan2
- ZAP70 | c.1813G>C p.E605Q | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.021); catalogued as COSV99385105; called by muse, mutect2
- ZBTB48 | c.1568G>A p.C523Y | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100887181; called by muse, mutect2, varscan2
- ZNF2 | c.340G>T p.D114Y (on ENST00000611147 / NM_001291605.2; = p.D101Y on NM_021088.4) | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV99728204; called by muse, mutect2, varscan2
- ZNF326 | c.113A>G p.Y38C | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100437828; called by muse, mutect2, varscan2
- ZNF365 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 21/88 reads (24%) | catalogued as rs762675434, COSV101237932; called by muse, mutect2, varscan2
- ACACA | c.1712del p.N571Ifs*45 | Frame Shift Del (DEL) | VAF 17/121 reads (14%) | called by mutect2, pindel, varscan2
- ACACB | c.659del p.S220Tfs*8 | Frame Shift Del (DEL) | VAF 21/57 reads (37%) | called by mutect2, pindel, varscan2
- GRAMD2A | c.137del p.L46Rfs*7 | Frame Shift Del (DEL) | VAF 20/78 reads (26%) | called by mutect2, pindel, varscan2
- PDZD2 | c.802_803del p.N268Wfs*25 | Frame Shift Del (DEL) | VAF 42/226 reads (19%) | called by mutect2, pindel, varscan2
- PTPRD | c.2211del p.N738Ifs*7 | Frame Shift Del (DEL) | VAF 44/116 reads (38%) | called by mutect2, pindel, varscan2
- RAI1 | c.5139del p.K1715Rfs*135 | Frame Shift Del (DEL) | VAF 21/111 reads (19%) | called by mutect2, pindel, varscan2
- TRGV5 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSEN34 | c.658_659insTAGC p.R220Lfs*25 | Frame Shift Ins (INS) | VAF 29/100 reads (29%) | called by mutect2, pindel, varscan2
- ABCA6 | c.978C>T p.V326= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV99445610; called by muse, mutect2, varscan2
- ANO5 | c.219C>T p.F73= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV100201309; called by muse, mutect2, varscan2
- CIDEC | c.285A>G p.E95= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV100396502; called by muse, mutect2
- EXD2 | c.1455C>T p.I485= (on ENST00000312994 / NM_001193362.1; = p.I360= on NM_018199.3) | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs371199925, COSV100473615; called by muse, mutect2, varscan2
- FAHD2B | c.117G>A p.G39= | Silent (SNP) | VAF 26/145 reads (18%) | catalogued as rs1420720039, COSV99737864; called by muse, mutect2, varscan2
- FLCN | c.516C>T p.I172= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV99550026; called by muse, mutect2, varscan2
- HGS | c.2124T>C p.P708= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV100230145; called by muse, mutect2, varscan2
- IGF2R | c.3222G>T p.A1074= | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as rs763107406, COSV100806738, COSV63626006; called by muse, mutect2, varscan2
- KMT5B | c.738A>T p.G246= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV100069812; called by muse, mutect2, varscan2
- MUC16 | c.10356C>A p.I3452= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV101197706, COSV67485841; called by muse, mutect2, varscan2
- MYH1 | c.3537C>T p.R1179= | Silent (SNP) | VAF 19/155 reads (12%) | catalogued as COSV99874701; called by muse, mutect2, varscan2
- NSD3 | c.3456G>A p.T1152= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as rs769133965, COSV100394839; called by muse, mutect2, varscan2
- NXF1 | c.1215G>T p.G405= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as COSV99585677; called by muse, mutect2, varscan2
- OR2T3 | c.117T>A p.L39= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as rs1357931080, COSV100613018; called by muse, mutect2, varscan2
- PAGR1 | c.91C>T p.L31= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs775253992, COSV100232554; called by muse, varscan2
- PTPRG | c.1398T>C p.S466= | Silent (SNP) | VAF 27/137 reads (20%) | catalogued as COSV99872476; called by muse, mutect2, varscan2
- SLC22A18 | c.1176C>T p.G392= | Silent (SNP) | VAF 17/144 reads (12%) | catalogued as rs200531595; called by muse, mutect2, varscan2
- TMC1 | c.1728C>T p.N576= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as rs761261855, COSV99918420; called by muse, mutect2, varscan2
- TRIM59 | c.1200A>T p.I400= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV100557399; called by muse, mutect2
- TXNDC16 | c.333C>T p.L111= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs138963960, COSV99908699; called by muse, mutect2, varscan2
- ZNF335 | c.2376G>A p.T792= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs146076876; called by muse, mutect2, varscan2
- ZNF507 | c.2406G>A p.K802= | Silent (SNP) | VAF 36/204 reads (18%) | catalogued as COSV100321499; called by muse, mutect2, varscan2
- ZNF518A | c.642C>T p.F214= | Silent (SNP) | VAF 23/156 reads (15%) | catalogued as rs920629004, COSV100283296; called by muse, mutect2, varscan2
- ZNF827 | c.2553C>T p.P851= | Silent (SNP) | VAF 44/89 reads (49%) | catalogued as COSV101061081; called by muse, mutect2, varscan2
- ZNRD2 | c.420T>G p.A140= | Silent (SNP) | VAF 34/151 reads (23%) | catalogued as COSV100326058; called by muse, mutect2, varscan2
- ZP3 | c.1155C>T p.T385= (on ENST00000394857 / NM_001110354.2; = p.T334= on NM_007155.6) | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs1446439902, COSV100334407; called by mutect2, varscan2
- ZRANB2 | c.642A>G p.S214= | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as COSV99638875; called by muse, mutect2, varscan2
- DNM3 | c.1689+13293G>A | Intron (SNP) | VAF 8/99 reads (8%) | catalogued as rs778608878, COSV62465874; called by muse, mutect2
- NOP56 | c.209-147G>T | Intron (SNP) | VAF 35/76 reads (46%) | catalogued as COSV100249910; called by muse, mutect2, varscan2
